Gene-level copy-number profile of tumor specimen ALCH-B1LE-TTP1-A from ALCHEMIST case ALCH-B1LE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.0 years (27,045 days).
Specimen ALCH-B1LE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 90f9f8d8-3690-44b6-9957-e5acde8c9164.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1LE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/8537c085-7a0d-4a6d-bf6a-af11631c30ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 661; copy number 1: 23,763; copy number 2: 29,047; copy number 3: 3,667; copy number 4: 1,763.

Homozygous deletions (total copy number 0; autosomes only): 149 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,164,919–10,243,745, 1 gene: IRAK2.
- chr3:53,156,009–53,192,717, 1 gene: PRKCD.
- chr5:181,193,924–181,342,213, 18 genes (within-gene range 0–1): TRIM7, TRIM7-AS1, AC008443.3, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:26,686,241–26,687,964, 1 gene: AL513548.1.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–1): POM121L6P.
- chr6:37,630,679–37,699,306, 1 gene: MDGA1.
- chr9:93,955,597–93,959,140, 1 gene: BARX1-DT.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:136,738,167–136,743,356, 1 gene (within-gene range 0–2): LCN10.
- chr10:103,745,966–103,755,423, 1 gene (within-gene range 0–1): SH3PXD2A-AS1.
- chr11:70,705,167–70,872,368, 4 genes (within-gene range 0–1): Y_RNA, AP000590.1, SHANK2-AS3, MIR3664.
- chr11:77,034,398–77,126,155, 3 genes (within-gene range 0–1): B3GNT6, CAPN5, OMP.
- chr13:111,865,136–111,901,264, 1 gene: LINC00354.
- chr15:25,170,723–25,204,438, 19 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr15:25,222,348–25,250,940, 17 genes (within-gene range 0–2): SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:50,548,396–53,504,411, 70 genes (broad region; genes not listed).
- chr17:35,756,249–35,795,707, 1 gene (within-gene range 0–1): MMP28.
- chr17:35,760,887–35,765,079, 1 gene (within-gene range 0–1): C17orf50.
- chr20:3,786,772–3,876,123, 5 genes: CDC25B, LINC01730, AL109804.1, AP5S1, MAVS.
- chr20:17,693,672–17,735,871, 1 gene: BANF2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 21,573. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
